Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4795, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4795-01A (Primary Tumor).

[page 1 of 2]
TCGA-BP-4795

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with right renal mass incidentally found.

Specimens Submitted:

1: SP: Right kidney; nephrectomy

2: SP: Lymph nodes, paracaval; excision

DIAGNOSIS:

1. SP: Right kidney; nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 1.5 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Marked glomerulosclerosis and chronic pyelonephritis

Adrenal Gland:

Not submitted

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: The tumor has "clear cell-papillary features" as has been described in kidneys with impaired renal function.

2. SP: Lymph nodes, paracaval; excision

Lymph Nodes:

Not involved

Number of nodes examined:2

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received fresh labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 150 g in total. The kidney measures 8 x 5 x 3.5 cm. The attached ureter measures 3 cm in length and 0.3 cm in diameter. No adrenal gland is identified. The kidney is inked black and bivalved to reveal a well circumscribed tan nodule in the upper pole, measuring 1.5 x 1.3 cm on cross-section. The tumor replaces the renal cortex, reaches but does not penetrate to the renal capsule, and pelvis. The renal parenchyma in the upper pole is brownish necrotic, with an ill defined corticomedullary junction. The renal parenchyma in the lower pole is relatively preserved. The cortex in this area measures 0.4 cm. No lymph node is identified. The entire tumor is submitted. TPS is taken. Representative sections are submitted.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

UK -- representative sections of upper pole kidney

LK -- representative sections lower pole kidney

F -- fat

2.) The specimen is received in formalin, labeled "paracaval lymph nodes" and consists of multiple pieces of fibroadipose tissue measuring 3.8 x 3.3 x 1.8 cm in aggregate. Within this tissue, two lymph nodes are identified measuring 1.3 and 0.6 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

Summary of Sections:

Part 1: SP: Right kidney; nephrectomy

Block	Sect. Site	PCs
1	F	1
1	LK	1
5	T	5
1	UK	1
1	UVM	1

Part 2: SP: Lymph nodes, paracaval; excision

Block	Sect. Site	PCs
1	LN	1

Source: NCI Genomic Data Commons file 1a1e630d-05c9-4e7e-bed7-856d01c756d8 (TCGA-BP-4795.999EDDF1-CD5C-4B00-B386-F628F920D28E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).